Somatic mutation profile of tumor specimen 0E1BO2 from CCDI case PBCURS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1BO2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60ccab01-14f3-4140-aedf-d4804614957b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1BO7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fd24dc1-315f-4007-b3d7-aa8f6acb5313

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5437G>C p.E1813Q | Missense Mutation (SNP) | VAF 100/459 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM160050, COSV58615431, COSV58617855; called by muse, varscan2
- DKK1 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 132/514 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1256593593; called by muse, varscan2
- SPTA1 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 148/537 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as rs931070390, COSV100934710; called by muse, varscan2
- CIB2 | c.542+1G>A p.X181_splice | Splice Site (SNP) | VAF 11/69 reads (16%) | called by muse, varscan2
- DHRS11 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, varscan2
- DPT | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.423); called by muse, varscan2
- MUC22 | c.2588C>A p.S863Y | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.31); called by muse, varscan2
- OR52A5 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 144/458 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, varscan2
- XDH | c.3597A>G p.A1199= | Silent (SNP) | VAF 44/174 reads (25%) | catalogued as rs573992165; called by muse, varscan2
- ADHFE1 | c.888-13A>G | Intron (SNP) | VAF 47/133 reads (35%) | catalogued as rs568450356; called by muse, varscan2
- GATB | c.1545+32G>A | Intron (SNP) | VAF 13/48 reads (27%) | called by muse, varscan2
